CPTAC case C3L-02900 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e5eaf10-f6f1-4ab1-b0bf-fc3e0718b6bb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1965; Vital status: Dead; Days to death: 1,053 days (2.9 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Occipital lobe; Age at diagnosis: 52.9 years (19,332 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 1,053 days (2.9 years); Progression or recurrence: no; Days to last follow up: 1,053 days (2.9 years).
   Pathology details: Greatest tumor dimension: 2.5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 343 days; Disease response: With Tumor.
- Days to follow up: 699 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 1,053 days (2.9 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 66.22 kg; Height: 172.72 cm; BMI: 22.2.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 20; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02900-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 219 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02900-21: Section location: Occipital Lobe; Percent tumor nuclei: 60; Percent necrosis: 25.
- Sample C3L-02900-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -1 day; Method of sample procurement: Blood Draw.
